Somatic mutation profile of tumor specimen 0DFMIS from CCDI case PBBSGJ, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 12.3 years (4,490 days).
Specimen 0DFMIS: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f8ae89f5-8f2f-44f8-a2ce-475f332a36b0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DFMIT (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/22d6dc47-92b2-4927-b36e-da97dcb0660b

The open-access MAF lists 21 somatic variants for this specimen: 16 protein-altering or splice-affecting, 3 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 14, Silent 3, Nonsense Mutation 1, RNA 1, Intron 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BMPR2 | c.180C>A p.C60* | Nonsense Mutation (SNP) | VAF 438/926 reads (47%) | catalogued as COSV65814092; called by muse, mutect2, varscan2
- CHST9 | c.460G>C p.D154H | Missense Mutation (SNP) | VAF 110/719 reads (15%) | SIFT tolerated (0.33); PolyPhen benign (0.125); catalogued as COSV52430985; called by muse, mutect2, varscan2
- COL18A1 | c.3460-2A>G p.X1154_splice (on ENST00000359759 / NM_130444.3; = p.X919_splice on NM_030582.4) | Splice Site (SNP) | VAF 170/401 reads (42%) | catalogued as rs1207980704; called by muse, mutect2, varscan2
- FER1L6 | c.71C>T p.A24V | Missense Mutation (SNP) | VAF 210/699 reads (30%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.238); catalogued as rs149657957; called by muse, mutect2, varscan2
- MGAT4C | c.446G>A p.R149H | Missense Mutation (SNP) | VAF 321/864 reads (37%) | SIFT tolerated (0.56); PolyPhen possibly damaging (0.69); catalogued as rs748796788, COSV59829726; called by muse, mutect2, varscan2
- PARD6A | c.334C>T p.R112W | Missense Mutation (SNP) | VAF 32/949 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV54670461; called by muse, mutect2
- PCDH17 | c.386C>T p.A129V | Missense Mutation (SNP) | VAF 129/294 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.594); catalogued as COSV64980270; called by muse, mutect2, varscan2
- TBR1 | c.823G>T p.G275C | Missense Mutation (SNP) | VAF 465/1155 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67417745; called by muse, mutect2, varscan2
- C17orf80 | c.843C>G p.S281R | Missense Mutation (SNP) | VAF 88/2062 reads (4%) | SIFT deleterious (0.05); PolyPhen benign (0.003); called by muse, mutect2
- HLTF | c.2692C>G p.Q898E | Missense Mutation (SNP) | VAF 55/1366 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.947); called by muse, mutect2
- KDM2B | c.2309G>C p.C770S | Missense Mutation (SNP) | VAF 330/755 reads (44%) | SIFT tolerated (0.75); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- LAMB4 | c.3176T>A p.L1059Q | Missense Mutation (SNP) | VAF 18/528 reads (3%) | SIFT tolerated (0.7); PolyPhen benign (0.012); called by muse, mutect2
- RTKN2 | c.729G>T p.L243F | Missense Mutation (SNP) | VAF 268/717 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.401); called by muse, mutect2, varscan2
- SLFN12L | c.368G>A p.S123N (on ENST00000260908 / NM_001363830.1; = p.S141N on NM_001195790.1) | Missense Mutation (SNP) | VAF 368/1610 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.431); called by muse, mutect2, varscan2
- TRAF6 | c.1280A>G p.Q427R | Missense Mutation (SNP) | VAF 117/768 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- ZNF716 | c.1288C>A p.H430N | Missense Mutation (SNP) | VAF 51/219 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- CDH16 | c.1272C>T p.G424= | Silent (SNP) | VAF 219/1096 reads (20%) | catalogued as rs145180383; called by muse, mutect2, varscan2
- CELF1 | c.807T>A p.A269= (on ENST00000358597 / NM_001376422.1; = p.A265= on NM_006560.4 and 10 other RefSeq transcripts) | Silent (SNP) | VAF 16/360 reads (4%) | catalogued as rs1167537044; called by muse, mutect2
- SLCO1B1 | c.657T>A p.G219= | Silent (SNP) | VAF 47/1166 reads (4%) | called by muse, mutect2
- CCDC140 | n.743C>G | RNA (SNP) | VAF 76/448 reads (17%) | called by muse, mutect2, varscan2
- EPB41L2 | c.1897-37G>A | Intron (SNP) | VAF 10/189 reads (5%) | called by muse, mutect2
